Somatic mutation profile of tumor specimen TCGA-63-7023-01A (aliquot TCGA-63-7023-01A-11D-1945-08) from TCGA case TCGA-63-7023, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA.
Specimen TCGA-63-7023-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07017629-ef00-48c7-ad74-5f4a03fa9ce0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-7023-10A (Blood Derived Normal), aliquot TCGA-63-7023-10A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f3570df-967c-4a39-9a08-3736510fc5c9

The open-access MAF lists 161 somatic variants for this specimen: 110 protein-altering or splice-affecting, 45 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 45, Frame Shift Del 8, RNA 6, Nonsense Mutation 5, Splice Site 4, Nonstop Mutation 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SERPINC1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28929469, CM890015, COSV100875021; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.2158A>T p.I720L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV99288183, COSV99288768; called by muse, mutect2, varscan2
- ABCC4 | c.3911A>G p.D1304G | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100972372; called by muse, mutect2, varscan2
- ADGRL1 | c.1527A>G p.G509= (on ENST00000340736 / NM_001008701.3; = p.G504= on NM_014921.5) | Splice Region (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100529358; called by muse, mutect2, varscan2
- AFDN | c.4886G>A p.R1629K (on ENST00000447894 / NM_001366320.1; = p.R1627K on NM_001040000.3) | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.006); catalogued as COSV100652717; called by muse, mutect2, varscan2
- AIDA | c.111-1G>T p.X37_splice | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100388148; called by muse, mutect2, varscan2
- AKAP3 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV57416682, COSV99961919; called by muse, mutect2, varscan2
- ANKRD2 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.234); catalogued as COSV100080772; called by muse, mutect2, varscan2
- ANKRD30A | c.1577C>A p.A526D (on ENST00000611781; = p.A470D on NM_052997.2) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV64608480; called by muse, mutect2, varscan2
- ARNT2 | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100308770; called by muse, mutect2, varscan2
- BICRAL | c.674T>C p.M225T | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs752474908, COSV100017947; called by muse, mutect2, varscan2
- C11orf49 | c.149+1G>A p.X50_splice | Splice Site (SNP) | VAF 59/140 reads (42%) | catalogued as COSV99561843; called by muse, mutect2, varscan2
- C3 | c.4121-2A>G p.X1374_splice | Splice Site (SNP) | VAF 37/139 reads (27%) | catalogued as COSV99836315; called by muse, mutect2, varscan2
- CAPG | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750346858, COSV99809323; called by muse, mutect2, varscan2
- CD200R1L | c.182A>T p.N61I | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.289); catalogued as COSV101236562; called by muse, mutect2, varscan2
- CHST2 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58886476; called by muse, mutect2
- CNR1 | c.399G>C p.E133D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100759189, COSV100759263; called by muse, mutect2, varscan2
- CNST | c.763G>C p.G255R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV100829825; called by muse, mutect2, varscan2
- COMMD4 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs756654687; called by muse, varscan2
- CR1 | c.41C>A p.P14Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.98); catalogued as rs769828093, COSV100887469, COSV65457809; called by muse, mutect2, varscan2
- CUBN | c.6125-1G>T p.X2042_splice | Splice Site (SNP) | VAF 24/50 reads (48%) | catalogued as COSV64716348; called by muse, mutect2, varscan2
- CYB5D2 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100028905; called by muse, mutect2, varscan2
- DRD5 | c.913T>C p.F305L | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100431648; called by muse, mutect2, varscan2
- DSCAM | c.5759G>T p.R1920M | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV101259577; called by muse, mutect2, varscan2
- DTWD1 | c.445A>T p.I149L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99233554; called by muse, mutect2, varscan2
- DZIP3 | c.381C>G p.H127Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100847704; called by muse, mutect2, varscan2
- ELAPOR2 | c.1094A>G p.Q365R (on ENST00000450689 / NM_001142749.3; = p.Q198R on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as COSV99788450; called by muse, mutect2, varscan2
- FGD3 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV100490464; called by muse, mutect2, varscan2
- FGF7 | c.479G>C p.G160A | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV51065559, COSV99983326, COSV99983371; called by muse, mutect2, varscan2
- FH | c.851A>G p.N284S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100844997; called by muse, mutect2, varscan2
- FILIP1L | c.3088G>T p.A1030S (on ENST00000354552 / NM_182909.3; = p.A790S on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV100496531; called by muse, mutect2, varscan2
- FREM2 | c.3267T>G p.H1089Q | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); catalogued as COSV99747702; called by muse, mutect2, varscan2
- GIMAP7 | c.374A>T p.K125M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100543616; called by muse, mutect2, varscan2
- GORAB | c.484C>G p.R162G | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100883760; called by muse, mutect2, varscan2
- GPC6 | c.1106C>A p.P369H | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV100988239; called by muse, mutect2, varscan2
- GRM8 | c.2223G>T p.K741N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV100281644; called by muse, mutect2, varscan2
- HBS1L | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV100122033; called by muse, mutect2, varscan2
- HNF4A | c.857A>T p.Y286F | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.047); catalogued as rs748714111, CM108585, COSV100291220; called by muse, mutect2, varscan2
- HP1BP3 | c.597G>T p.R199S | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100391659; called by muse, mutect2, varscan2
- IMMP1L | c.25A>T p.T9S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99540788; called by muse, mutect2, varscan2
- INTS5 | c.2190C>A p.D730E | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100399536; called by muse, mutect2, varscan2
- KCNJ3 | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV99715462; called by muse, mutect2, varscan2
- KIAA0100 | c.990G>C p.Q330H | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV101197253; called by muse, mutect2, varscan2
- KMT2D | c.11128G>T p.G3710* | Nonsense Mutation (SNP) | VAF 29/77 reads (38%) | catalogued as COSV56479010, COSV99978990; called by muse, mutect2, varscan2
- KRT6C | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs1245737548, COSV99359887; called by muse, mutect2, varscan2
- LRRC4 | c.789C>A p.D263E | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.638); catalogued as COSV99974816; called by muse, mutect2, varscan2
- MAG | c.1742G>A p.R581K | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT tolerated (0.86); PolyPhen benign (0.386); catalogued as COSV100727685; called by muse, mutect2, varscan2
- MMP16 | c.851A>G p.Q284R | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99686869; called by muse, mutect2, varscan2
- MUC16 | c.20725G>T p.E6909* | Nonsense Mutation (SNP) | VAF 127/280 reads (45%) | catalogued as COSV101198974; called by muse, mutect2, varscan2
- MYH2 | c.5347G>A p.A1783T | Missense Mutation (SNP) | VAF 66/86 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs759668950, COSV55444055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9A | c.3848C>G p.A1283G | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs751664418, COSV100612974; called by muse, mutect2, varscan2
- NCKAP5 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV100490843; called by muse, mutect2, varscan2
- NCOA3 | c.3653A>C p.Q1218P (on ENST00000371998 / NM_181659.3; = p.Q1214P on NM_006534.4) | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as COSV100507318; called by muse, mutect2, varscan2
- NEB | c.19639A>G p.S6547G | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.986); catalogued as COSV99417971; called by muse, varscan2
- NEB | c.19624A>T p.S6542C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99417978; called by muse, varscan2
- NEXMIF | c.3637G>T p.G1213C | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV99280193; called by muse, mutect2, varscan2
- NRXN3 | c.598A>T p.T200S (on ENST00000557594 / NM_001272020.2; = p.T832S on NM_004796.6) | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99817156; called by muse, mutect2, varscan2
- OR10H3 | c.895C>A p.L299M | Missense Mutation (SNP) | VAF 108/124 reads (87%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.999); catalogued as COSV100008347; called by muse, mutect2, varscan2
- OR11H12 | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV101612471; called by muse, varscan2
- OR14C36 | c.114G>T p.M38I | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV58602136, COSV58603027; called by muse, mutect2, varscan2
- OR1B1 | c.554G>C p.C185S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100506434; called by muse, mutect2, varscan2
- OR2B3 | c.607A>T p.S203C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.109); catalogued as COSV101013767; called by muse, mutect2, varscan2
- OR4K1 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53463202; called by muse, mutect2, varscan2
- OR52N4 | c.320A>T p.H107L | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100421632; called by muse, mutect2, varscan2
- PAPPA2 | c.5111T>G p.M1704R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as COSV62792693; called by muse, mutect2, varscan2
- PARP9 | c.151T>G p.S51A | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100831003; called by muse, mutect2, varscan2
- PDP1 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99892140; called by muse, mutect2, varscan2
- PGBD1 | c.594C>A p.N198K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1480567453, COSV99459919; called by muse, varscan2
- PITPNB | c.197G>A p.S66N | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100086671; called by muse, mutect2, varscan2
- PJA1 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 15/16 reads (94%) | catalogued as rs753903640, COSV64052946; called by muse, mutect2, varscan2
- PLAGL1 | c.564C>A p.F188L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV99394230; called by muse, mutect2, varscan2
- PLCE1 | c.5810G>A p.R1937H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314937548, COSV53360217, COSV53371322; called by muse, mutect2, varscan2
- PLXNA4 | c.130C>G p.R44G | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV100323282, COSV58142761; called by muse, mutect2, varscan2
- PPFIA4 | c.3082G>C p.D1028H (on ENST00000447715; = p.D1029H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99690391; called by muse, mutect2, varscan2
- PRLR | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99184262; called by muse, mutect2, varscan2
- RAET1G | c.740T>C p.L247P | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV100951648; called by muse, mutect2, varscan2
- SACS | c.11122C>G p.P3708A | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as rs1177654572, COSV101207267; called by muse, mutect2, varscan2
- SECISBP2 | c.2143A>T p.I715F | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100358109; called by muse, mutect2, varscan2
- SIN3B | c.2100C>G p.F700L | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV99931543; called by muse, mutect2, varscan2
- SLCO1C1 | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 52/356 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.179); catalogued as COSV56871867, COSV56872540; called by muse, mutect2, varscan2
- SLCO5A1 | c.78G>T p.E26D | Missense Mutation (SNP) | VAF 105/171 reads (61%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99479658; called by muse, mutect2, varscan2
- SOX11 | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100430922; called by muse, mutect2, varscan2
- SPAM1 | c.360A>T p.L120F | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99772846; called by muse, mutect2, varscan2
- SPG11 | c.2399A>T p.Y800F | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV99968285; called by muse, mutect2, varscan2
- STRAP | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV50309548, COSV99214720; called by muse, mutect2, varscan2
- SYNJ2 | c.1822G>T p.G608C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV100840093; called by muse, mutect2, varscan2
- TCTN2 | c.2050T>C p.F684L | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100315137; called by muse, mutect2, varscan2
- TEP1 | c.5966A>G p.D1989G | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99401930; called by muse, mutect2, varscan2
- THBD | c.1231A>T p.T411S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV101001863; called by muse, mutect2, varscan2
- TOLLIP | c.167A>G p.N56S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99719480; called by muse, varscan2
- TTN | c.11818G>A p.A3940T (on ENST00000591111; = p.A3894T on NM_003319.4) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100601571, COSV60466287; called by muse, mutect2, varscan2
- TUBA3C | c.1096G>T p.G366* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as COSV101313846, COSV68029603; called by muse, mutect2, varscan2
- UBR5 | c.6331G>A p.V2111I | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.785); catalogued as COSV99640092; called by muse, mutect2, varscan2
- VCAN | c.601C>A p.L201M | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99425148; called by muse, mutect2, varscan2
- WDR72 | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs1200122301, COSV64754505; called by muse, mutect2, varscan2
- WNK1 | c.5602G>C p.G1868R (on ENST00000315939 / NM_018979.4; = p.G1620R on NM_014823.3) | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100266714, COSV60045761; called by muse, mutect2, varscan2
- ZMYM1 | c.3429A>T p.*1143Yext*5 | Nonstop Mutation (SNP) | VAF 7/10 reads (70%) | catalogued as COSV100720929; called by muse, mutect2, varscan2
- ZNF117 | c.462A>T p.K154N | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as COSV51426704, COSV99275355; called by muse, mutect2, varscan2
- ZNF654 | c.2933A>T p.N978I | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100525657; called by muse, mutect2, varscan2
- ZNF80 | c.154A>T p.K52* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV100351974; called by muse, mutect2, varscan2
- ARID1A | c.5817del p.P1940Hfs*16 | Frame Shift Del (DEL) | VAF 52/94 reads (55%) | called by mutect2, pindel, varscan2
- BRD7 | c.1368_1372del p.Y457Hfs*4 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- IGKV1D-17 | c.127A>G p.I43V | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- KMT2D | c.9265del p.V3089Wfs*30 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- NALCN | c.1276del p.T426Qfs*10 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | called by mutect2, pindel, varscan2
- NDST1 | c.103del p.A35Pfs*144 | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | called by pindel, varscan2
- NLRP14 | c.1117del p.W373Gfs*7 | Frame Shift Del (DEL) | VAF 42/137 reads (31%) | called by mutect2, pindel, varscan2
- PKMYT1 | c.1449del p.F483Lfs*14 | Frame Shift Del (DEL) | VAF 13/24 reads (54%) | called by mutect2, pindel, varscan2
- SCN2A | c.836dup p.L279Ffs*7 | Frame Shift Ins (INS) | VAF 44/106 reads (42%) | called by mutect2, pindel, varscan2
- TLE1 | c.1417del p.R473Gfs*18 | Frame Shift Del (DEL) | VAF 31/100 reads (31%) | called by mutect2, pindel, varscan2
- ABCB11 | c.939T>C p.R313= | Silent (SNP) | VAF 57/116 reads (49%) | catalogued as COSV99791782; called by muse, mutect2, varscan2
- AHCTF1 | c.1941C>T p.F647= (on ENST00000366508; = p.F621= on NM_015446.5) | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100403374, COSV58248085; called by muse, varscan2
- ARHGAP45 | c.1773G>A p.G591= | Silent (SNP) | VAF 42/70 reads (60%) | catalogued as COSV100490527; called by muse, mutect2, varscan2
- C12orf42 | c.843G>T p.A281= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as COSV100171958; called by muse, mutect2, varscan2
- CANX | c.1713A>G p.K571= | Silent (SNP) | VAF 12/13 reads (92%) | catalogued as COSV99910319; called by muse, mutect2, varscan2
- CDC25C | c.411C>A p.G137= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV100086589; called by muse, mutect2, varscan2
- CEP290 | c.6567C>T p.S2189= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1253867962, COSV100468168; called by muse, varscan2
- COL16A1 | c.2904G>C p.G968= | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as COSV99593856; called by muse, mutect2, varscan2
- DNAJC2 | c.1716T>C p.N572= | Silent (SNP) | VAF 58/145 reads (40%) | catalogued as COSV99971170; called by muse, mutect2, varscan2
- DPP4 | c.1266T>C p.Y422= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV100858756; called by muse, mutect2, varscan2
- FCRL1 | c.99A>T p.P33= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV100839745; called by muse, mutect2, varscan2
- FCRL3 | c.1899A>G p.Q633= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV100943008; called by muse, mutect2, varscan2
- FMN2 | c.1242C>A p.I414= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV100144046, COSV60421941; called by muse, mutect2, varscan2
- FMN2 | c.4101A>T p.A1367= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV100142860, COSV100144048; called by muse, mutect2, varscan2
- FOXD4L4 | c.438C>T p.R146= | Silent (SNP) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- FOXD4L5 | c.438C>T p.R146= | Silent (SNP) | VAF 10/40 reads (25%) | called by mutect2, varscan2
- IAPP | c.105C>T p.C35= | Silent (SNP) | VAF 32/285 reads (11%) | catalogued as rs748654986, COSV99557013; called by muse, mutect2, varscan2
- IGHM | c.894G>A p.G298= | Silent (SNP) | VAF 19/21 reads (90%) | called by muse, mutect2, varscan2
- INTS4 | c.687A>G p.L229= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV101417155; called by muse, mutect2, varscan2
- JAK2 | c.798C>T p.Y266= | Silent (SNP) | VAF 32/40 reads (80%) | catalogued as rs746680840, COSV101071694; called by muse, mutect2, varscan2
- L1CAM | c.963C>A p.A321= | Silent (SNP) | VAF 56/65 reads (86%) | catalogued as COSV100648948, COSV62830566; called by muse, mutect2, varscan2
- MUC6 | c.5298C>T p.T1766= | Silent (SNP) | VAF 92/716 reads (13%) | called by muse, varscan2
- NEB | c.12144G>C p.L4048= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs564752449, COSV99417984; called by muse, mutect2, varscan2
- NPHS2 | c.951T>G p.A317= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV100858138; called by muse, mutect2, varscan2
- NTRK3 | c.975G>A p.V325= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs777384222, COSV100446142; called by muse, mutect2, varscan2
- OR14A16 | c.333C>A p.L111= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV100713728, COSV100713865; called by muse, mutect2, varscan2
- OR4K1 | c.852C>A p.P284= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV99578788; called by muse, mutect2, varscan2
- OR52A5 | c.891G>A p.V297= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100263282, COSV56614260; called by muse, mutect2, varscan2
- OR5D14 | c.735C>A p.S245= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV100162255; called by muse, mutect2, varscan2
- OTX1 | c.159C>T p.L53= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs997215139, COSV99246227; called by muse, mutect2, varscan2
- PKHD1 | c.11952A>T p.P3984= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as COSV100944068; called by muse, mutect2, varscan2
- PTPRN2 | c.1407G>A p.A469= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs765722971, COSV67023396; called by muse, mutect2, varscan2
- SEMA6D | c.2670T>C p.N890= (on ENST00000316364 / NM_153618.2; = p.N828= on NM_020858.2) | Silent (SNP) | VAF 57/112 reads (51%) | catalogued as COSV100316668; called by muse, mutect2, varscan2
- SI | c.3735T>A p.A1245= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100014636; called by muse, mutect2, varscan2
- SLC2A3 | c.1476C>A p.T492= | Silent (SNP) | VAF 390/666 reads (59%) | catalogued as COSV99306366; called by muse, varscan2
- SLCO1C1 | c.393C>T p.F131= | Silent (SNP) | VAF 508/614 reads (83%) | catalogued as rs1488353170, COSV56872196, COSV56876493; called by muse, mutect2, varscan2
- SMG1 | c.9870T>A p.L3290= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV101245479; called by muse, mutect2, varscan2
- TECTA | c.945C>T p.S315= | Silent (SNP) | VAF 41/45 reads (91%) | catalogued as rs758060391, COSV99879154; called by muse, mutect2, varscan2
- TENM3 | c.247C>T p.L83= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV101304975; called by muse, mutect2, varscan2
- TRIM45 | c.1059G>T p.R353= | Silent (SNP) | VAF 7/112 reads (6%) | catalogued as rs1298602907, COSV99868333; called by muse, mutect2
- UACA | c.1041G>A p.K347= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100537393; called by muse, mutect2, varscan2
- VPS50 | c.2049T>C p.L683= | Silent (SNP) | VAF 69/148 reads (47%) | catalogued as COSV100004644; called by muse, mutect2, varscan2
- ZBTB2 | c.330A>G p.E110= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as COSV100287548; called by muse, mutect2, varscan2
- ZFHX4 | c.5085G>A p.Q1695= | Silent (SNP) | VAF 82/124 reads (66%) | catalogued as COSV99259916; called by muse, mutect2, varscan2
- ZNF831 | c.1542G>A p.R514= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100925901; called by muse, mutect2, varscan2
- ADGRE4P | n.230A>C | RNA (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- LINC02872 | n.433T>G | RNA (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- MIR325 | n.30A>T | RNA (SNP) | VAF 63/71 reads (89%) | called by muse, mutect2, varscan2
- SNORD115-8 | n.16A>G | RNA (SNP) | VAF 109/282 reads (39%) | called by muse, mutect2, varscan2
- SNORD116-17 | n.21A>G | RNA (SNP) | VAF 67/168 reads (40%) | catalogued as rs760845477; called by muse, mutect2, varscan2
- TMEM183B | n.358A>T | RNA (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
